Surgical pathology report (de-identified scan), TCGA case TCGA-G2-A2EF, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-A2EF-01A (Primary Tumor).

PATHOLOGY REPORTS

1CD-0-3

Carcinoma, urothelial, nos 8120/3

Situ: bladder wall, nos C67.9

hw
5/31/11

DIAGNOSIS

(A) BLADDER TUMOR, LEFT WALL:

UROTHELIAL CARCINOMA, HIGH GRADE (GRADE 3), WITH SQUAMOUS
DIFFERENTIATION, INVASIVE INTO

MUSCULARIS PROPRIA, WITH LYMPHOVASCULAR INVASION.

Extensive necrosis, inflammation and reactive changes are also present.

GROSS DESCRIPTION

(A) BLADDER TUMOR, LEFT WALL - Received are multiple fragments of pink-gray friable/rubbery tissue measuring in aggregate, 4.0 x 4.0 x 3.5 cm. Entirely submitted in cassettes A1-A6.

CLINICAL HISTORY

Bladder cancer.

Source: NCI Genomic Data Commons file baa9588d-ac96-492e-97b0-b16056ac479d (TCGA-G2-A2EF.6C7C3694-0D25-476F-BCAF-83BCC10C7C3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).